Somatic mutation profile of tumor specimen PCProject_0588_T2_WES (aliquot PCProject_0588_T2_WES_1) from CMI case PCProject_0588, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.7 years (23,280 days).
Specimen PCProject_0588_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 646b9b5f-bdc9-4e1d-9c35-461aae142078.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0588_SALIVA (Saliva), aliquot PCProject_0588_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a60385d1-a56d-4644-bcfe-a9bbaceba119

The open-access MAF lists 139 somatic variants for this specimen: 49 protein-altering or splice-affecting, 24 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 42, Missense Mutation 42, Silent 24, 3'UTR 11, RNA 5, 5'Flank 4, 3'Flank 3, Frame Shift Del 3, Nonsense Mutation 2, 5'UTR 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA1A | c.1350A>C p.R450S | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1161985421; called by muse, varscan2
- ARHGAP8 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1187087068; called by mutect2, varscan2
- BCAN | c.2594A>T p.E865V | Missense Mutation (SNP) | VAF 118/315 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs761374302; called by muse, mutect2, varscan2
- DYNC1I1 | c.1804A>G p.T602A | Missense Mutation (SNP) | VAF 20/271 reads (7%) | catalogued as rs1373216727, COSV73359662; called by muse, mutect2
- DYNC1LI2 | c.44A>G p.N15S | Missense Mutation (SNP) | VAF 102/865 reads (12%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs779213659; called by muse, varscan2
- EPHA10 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 121/476 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370728811, COSV60405151; called by muse, mutect2, varscan2
- ETV3 | c.185G>C p.G62A | Missense Mutation (SNP) | VAF 64/305 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100460975; called by muse, mutect2, varscan2
- FLG | c.6482C>T p.S2161F | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1191873733, COSV100912401, COSV64244120; called by muse, mutect2, varscan2
- FOXD4L5 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 76/1665 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV101073109; called by muse, mutect2
- GJD4 | c.797del p.P266Rfs*33 | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | catalogued as rs1186593549; called by mutect2, pindel, varscan2
- GLRB | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV52412919; called by mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | catalogued as rs754199513; called by mutect2, varscan2
- GUCY1A2 | c.2128C>A p.L710I | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV56496094; called by mutect2, varscan2
- KNDC1 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as rs541722509, COSV58845042; called by mutect2, varscan2
- MADD | c.4106G>A p.R1369H | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1432575744; called by muse, mutect2, varscan2
- MEIS2 | c.1315A>G p.M439V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV54930798, COSV54945955; called by muse, varscan2
- MGA | c.4204T>A p.C1402S | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54948532; called by muse, varscan2
- MTO1 | c.1156A>C p.M386L | Missense Mutation (SNP) | VAF 77/480 reads (16%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs997481152, COSV64773224; called by muse, varscan2
- NEB | c.8528T>A p.F2843Y | Missense Mutation (SNP) | VAF 31/410 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV50807851; called by muse, varscan2
- RYR1 | c.7772G>A p.R2591Q | Missense Mutation (SNP) | VAF 63/566 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as COSV62091521; called by muse, mutect2, varscan2
- SHC4 | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs192668089; called by muse, mutect2, varscan2
- SNX31 | c.82G>C p.G28R | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT tolerated (1); catalogued as rs1013488383; called by muse, mutect2
- TENT2 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs549225169, COSV57134825; called by muse, mutect2, varscan2
- UGT8 | c.954A>T p.K318N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV60421595; called by muse, mutect2, varscan2
- UXT | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs868164862; called by muse, varscan2
- ANKRD11 | c.-60+2T>C | Splice Site (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- ASAH2 | c.1349C>A p.P450Q | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- BVES | c.94A>G p.T32A | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CARD11 | c.2765T>C p.I922T | Missense Mutation (SNP) | VAF 58/412 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD163L1 | c.2429T>C p.V810A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDK12 | c.2338C>T p.Q780* | Nonsense Mutation (SNP) | VAF 24/253 reads (9%) | called by muse, mutect2
- CDK12 | c.3011A>G p.D1004G | Missense Mutation (SNP) | VAF 93/181 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDR1 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2
- CLSTN3 | c.1664A>G p.Y555C | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- COL24A1 | c.2488G>C p.A830P | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.97); PolyPhen benign (0.01); called by muse, mutect2
- DLGAP3 | c.2596G>C p.V866L | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ECPAS | c.4159G>T p.D1387Y | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- FAM171A1 | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- FOXA1 | c.768del p.N256Kfs*65 | Frame Shift Del (DEL) | VAF 94/197 reads (48%) | called by mutect2, pindel, varscan2
- FPGT-TNNI3K | c.1739A>T p.H580L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.747); called by mutect2, varscan2
- HMCN1 | c.8041C>T p.P2681S | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MFSD4A | c.1034A>G p.H345R | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR7G3 | c.688del p.S230Qfs*16 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | called by mutect2, pindel, varscan2
- OTOP1 | c.1234A>T p.I412F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- PTPRB | c.4575G>T p.Q1525H | Missense Mutation (SNP) | VAF 25/347 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PYGM | c.1336T>C p.C446R | Missense Mutation (SNP) | VAF 181/451 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- RAPGEF4 | c.1527A>T p.L509F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZBTB7B | c.1009G>A p.V337M (on ENST00000292176; = p.V371M on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/435 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF469 | c.11514C>A p.S3838R (on ENST00000437464; = p.S3866R on NM_001367624.2) | Missense Mutation (SNP) | VAF 155/364 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- ACP1 | c.55C>A p.R19= | Silent (SNP) | VAF 42/103 reads (41%) | called by muse, mutect2, varscan2
- AP3B1 | c.2544T>C p.G848= | Silent (SNP) | VAF 92/264 reads (35%) | called by muse, mutect2, varscan2
- BHLHA15 | c.228G>T p.R76= | Silent (SNP) | VAF 232/1900 reads (12%) | called by muse, varscan2
- C6orf118 | c.54G>T p.T18= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs202066157, COSV57816580; called by muse, mutect2, varscan2
- DCTN4 | c.501G>A p.L167= | Silent (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2, varscan2
- EXTL1 | c.483C>A p.V161= | Silent (SNP) | VAF 62/190 reads (33%) | catalogued as COSV100959048; called by muse, mutect2, varscan2
- FUBP1 | c.540C>T p.G180= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as rs1049520773; called by muse, mutect2
- GALNTL6 | c.708G>A p.E236= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- IFT80 | c.2184A>G p.K728= | Silent (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2
- IPO13 | c.1143A>G p.V381= | Silent (SNP) | VAF 9/118 reads (8%) | called by muse, mutect2
- IPO7 | c.1215A>G p.K405= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs753955265, COSV63352932; called by muse, mutect2, varscan2
- KCNQ4 | c.1008G>A p.E336= | Silent (SNP) | VAF 99/493 reads (20%) | called by muse, mutect2, varscan2
- MATR3 | c.810A>G p.R270= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV63075533; called by muse, mutect2, varscan2
- MTMR9 | c.522G>A p.R174= | Silent (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- MUC16 | c.37635G>C p.L12545= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as rs779198387; called by muse, mutect2, varscan2
- MYL6 | c.109A>C p.R37= | Silent (SNP) | VAF 20/230 reads (9%) | catalogued as COSV52878182, COSV52879146; called by muse, mutect2
- NEB | c.8529C>T p.F2843= | Silent (SNP) | VAF 32/410 reads (8%) | catalogued as COSV50807815, COSV51443776; called by muse, varscan2
- OR52N1 | c.648T>C p.I216= | Silent (SNP) | VAF 39/177 reads (22%) | called by muse, mutect2, varscan2
- PCDH9 | c.3282T>C p.Y1094= (on ENST00000377865 / NM_203487.3; = p.Y1060= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs1289485922, COSV60524944; called by muse, varscan2
- PIK3CG | c.2235C>A p.V745= | Silent (SNP) | VAF 52/112 reads (46%) | catalogued as COSV63252730; called by muse, varscan2
- RYR1 | c.6714T>C p.Y2238= | Silent (SNP) | VAF 18/386 reads (5%) | called by muse, mutect2
- SMARCA5 | c.1593T>A p.G531= | Silent (SNP) | VAF 17/92 reads (18%) | called by muse, varscan2
- SPANXN2 | c.429A>T p.S143= | Silent (SNP) | VAF 46/144 reads (32%) | called by muse, varscan2
- UBASH3A | c.561C>T p.S187= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs373568437; called by muse, mutect2, varscan2
- AC002511.3 | n.324+51A>G | Intron (SNP) | VAF 10/96 reads (10%) | catalogued as rs1253745522; called by muse, varscan2
- AC008752.3 | chr19:9752394 A>G | 3'Flank (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- AC022517.1 | chr19:5174050 A>C | 5'Flank (SNP) | VAF 30/252 reads (12%) | catalogued as rs1228929187; called by muse, mutect2, varscan2
- AC099654.5 | n.31C>G | RNA (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
- AC104472.1 | n.238T>C | RNA (SNP) | VAF 29/250 reads (12%) | called by muse, varscan2
- ADAM10 | c.207-16014C>A | Intron (SNP) | VAF 26/279 reads (9%) | called by muse, mutect2, varscan2
- AK7 | c.2134-276T>C | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs1334656460; called by mutect2, varscan2
- AL359555.4 | n.262A>G | RNA (SNP) | VAF 20/164 reads (12%) | catalogued as rs1283437697; called by muse, varscan2
- AREL1 | c.482-1550G>C | Intron (SNP) | VAF 9/58 reads (16%) | catalogued as rs968026826; called by muse, mutect2
- ASCC1 | c.112+943A>G | Intron (SNP) | VAF 12/124 reads (10%) | called by mutect2, varscan2
- ATP6V1E1 | c.99+357G>A | Intron (SNP) | VAF 8/76 reads (11%) | catalogued as rs1437671681; called by mutect2, varscan2
- CAMTA1 | c.234+46564T>C | Intron (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- CCDC198 | c.656-3924A>G | Intron (SNP) | VAF 10/78 reads (13%) | catalogued as rs1342522248; called by muse, mutect2
- CCDC198 | c.656-4078A>G | Intron (SNP) | VAF 38/245 reads (16%) | catalogued as rs1303405509; called by muse, varscan2
- CD55 | c.1081+1172T>C | Intron (SNP) | VAF 20/210 reads (10%) | catalogued as rs1260729418; called by muse, varscan2
- CDK10 | c.87+901A>G | Intron (SNP) | VAF 18/119 reads (15%) | catalogued as rs1334746439; called by muse, varscan2
- CPLANE2 | chr1:16229036 A>G | 3'Flank (SNP) | VAF 25/213 reads (12%) | called by muse, varscan2
- DNAJC19 | c.*690A>G | 3'UTR (SNP) | VAF 8/55 reads (15%) | catalogued as rs1370714837, COSV104423365; called by muse, varscan2
- DOCK8 | c.53+5787A>G | Intron (SNP) | VAF 14/70 reads (20%) | catalogued as rs1332353867; called by muse, mutect2
- DOT1L | c.*19G>T | 3'UTR (SNP) | VAF 83/392 reads (21%) | called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1512+724G>C | Intron (SNP) | VAF 22/229 reads (10%) | catalogued as rs1409645313, COSV57516703; called by muse, varscan2
- EPS15 | c.561+2465G>T | Intron (SNP) | VAF 22/240 reads (9%) | called by muse, varscan2
- FAM157A | n.36C>T | RNA (SNP) | VAF 79/441 reads (18%) | catalogued as rs1257319666; called by muse, mutect2, varscan2
- FAM193B | c.2372+727A>G | Intron (SNP) | VAF 13/121 reads (11%) | called by muse, varscan2
- FBP1 | c.*20C>A | 3'UTR (SNP) | VAF 31/225 reads (14%) | called by muse, mutect2, varscan2
- FDFT1 | chr8:11801917 T>C | 5'Flank (SNP) | VAF 14/130 reads (11%) | catalogued as rs1217988127; called by muse, mutect2
- GATC | c.255-2062G>A | Intron (SNP) | VAF 30/279 reads (11%) | called by muse, varscan2
- GLT8D2 | c.112+667A>G | Intron (SNP) | VAF 8/142 reads (6%) | catalogued as rs1373674070; called by muse, mutect2
- IFT122 | c.272+674A>G | Intron (SNP) | VAF 23/231 reads (10%) | catalogued as rs998282185; called by muse, varscan2
- IFT74 | c.305+1755T>C | Intron (SNP) | VAF 45/780 reads (6%) | catalogued as rs1231649367; called by muse, mutect2
- IGHV5-51 | c.-24C>A | 5'UTR (SNP) | VAF 10/106 reads (9%) | called by muse, varscan2
- IL6R | c.949+1429A>G | Intron (SNP) | VAF 26/180 reads (14%) | catalogued as rs1433692516, COSV59815634; called by muse, varscan2
- KCNIP4 | c.62-421186A>G | Intron (SNP) | VAF 6/60 reads (10%) | called by muse, varscan2
- KLHL2 | c.152+3907A>G | Intron (SNP) | VAF 31/360 reads (9%) | called by muse, varscan2
- LRRC69 | c.184-6251T>C | Intron (SNP) | VAF 15/171 reads (9%) | catalogued as rs1206479862, COSV59258003; called by muse, mutect2, varscan2
- MROH7 | c.1231+4994A>G | Intron (SNP) | VAF 27/149 reads (18%) | catalogued as rs1280737551; called by muse, varscan2
- NLE1 | c.1214+282T>C | Intron (SNP) | VAF 22/178 reads (12%) | called by muse, varscan2
- NPIPP1 | n.1051C>T | RNA (SNP) | VAF 16/125 reads (13%) | catalogued as rs202168202, COSV104415369, COSV62592452; called by muse, varscan2
- NRG1 | c.502+31246G>C | Intron (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- PADI4 | c.340+485A>G | Intron (SNP) | VAF 14/78 reads (18%) | catalogued as rs1036598090; called by muse, varscan2
- PDCD6IP | c.210-919A>G | Intron (SNP) | VAF 13/129 reads (10%) | catalogued as rs1473774163; called by muse, varscan2
- PHC3 | c.379-1423A>G | Intron (SNP) | VAF 25/136 reads (18%) | catalogued as rs1490286380; called by muse, varscan2
- QRSL1 | c.*50A>G | 3'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as rs1438819257; called by mutect2, varscan2
- RAB26 | c.307-418T>A | Intron (SNP) | VAF 26/341 reads (8%) | catalogued as rs1407315531; called by muse, mutect2
- RBL2 | c.993-400A>G | Intron (SNP) | VAF 41/334 reads (12%) | catalogued as rs1426585233; called by muse, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 23/176 reads (13%) | catalogued as rs910081914; called by muse, mutect2
- RNF4 | c.125-1317G>A | Intron (SNP) | VAF 31/254 reads (12%) | catalogued as rs1319401008; called by muse, varscan2
- SHANK2 | c.1108-11326T>C | Intron (SNP) | VAF 37/614 reads (6%) | called by muse, mutect2
- SPATA21 | c.35-3144A>G | Intron (SNP) | VAF 9/45 reads (20%) | catalogued as rs1172984767; called by muse, varscan2
- SSR1 | c.699+861G>T | Intron (SNP) | VAF 22/190 reads (12%) | catalogued as rs1158642912; called by muse, varscan2
- TMEM67 | chr8:93819062 A>C | 3'Flank (SNP) | VAF 40/388 reads (10%) | called by muse, mutect2
- TMIGD2 | c.*107A>G | 3'UTR (SNP) | VAF 32/343 reads (9%) | called by muse, mutect2
- TMPRSS3 | c.*374A>G | 3'UTR (SNP) | VAF 42/396 reads (11%) | catalogued as rs1392490704; called by muse, varscan2
- TNFRSF10B | c.*2072G>C | 3'UTR (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.552-1041A>G | Intron (SNP) | VAF 34/234 reads (15%) | called by mutect2, varscan2
- TRIM56 | c.*2108T>C | 3'UTR (SNP) | VAF 26/292 reads (9%) | called by mutect2, varscan2
- WNK4 | c.2295+185A>G | Intron (SNP) | VAF 18/149 reads (12%) | catalogued as rs1366214435; called by muse, varscan2
- XIAP | c.*5652C>T | 3'UTR (SNP) | VAF 13/64 reads (20%) | catalogued as rs200661683; called by muse, varscan2
- XIAP | c.*5664A>G | 3'UTR (SNP) | VAF 14/128 reads (11%) | catalogued as rs1256618390; called by muse, varscan2
- XIAP | c.*6045G>C | 3'UTR (SNP) | VAF 7/68 reads (10%) | called by mutect2, varscan2
- XPO5 | c.2678-356T>C | Intron (SNP) | VAF 22/299 reads (7%) | catalogued as rs1242378776, COSV54830476; called by muse, mutect2
- ZBTB8A | chr1:32536198 C>G | 5'Flank (SNP) | VAF 29/488 reads (6%) | called by muse, mutect2
- ZNF131 | chr5:43120013 A>G | 5'Flank (SNP) | VAF 34/226 reads (15%) | catalogued as rs1163968436; called by muse, mutect2
- ZNF141 | c.226+13814A>G | Intron (SNP) | VAF 26/211 reads (12%) | catalogued as rs1553851530; called by muse, varscan2
- ZNF195 | c.226+4114G>A | Intron (SNP) | VAF 12/83 reads (14%) | called by mutect2, varscan2
- ZNF74 | c.121-993T>C | Intron (SNP) | VAF 18/94 reads (19%) | catalogued as rs1332791828; called by muse, varscan2
